CCDI case PBCNRG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b802734f-f9d1-4c20-9274-98689bae0cf0

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Diagnosis record without a diagnosis name: Tissue or organ of origin: Overlapping lesion of brain; Age at diagnosis: 6.3 years (2,319 days).

Biospecimens (3 samples)
- Sample 0DW6B2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DW6B9: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DW6BQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
